Somatic mutation profile of tumor specimen TCGA-ET-A40Q-01A (aliquot TCGA-ET-A40Q-01A-11D-A23M-08) from TCGA case TCGA-ET-A40Q, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 38.7 years (14,136 days).
Specimen TCGA-ET-A40Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbe07e5d-cdb5-49fd-98f3-22c6acb60ee1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A40Q-10A (Blood Derived Normal), aliquot TCGA-ET-A40Q-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eba147b1-d1fe-43d3-9d25-92723ae42c10

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Splice Site 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARMC12 | c.794C>T p.P265L (on ENST00000373866 / NM_001286574.2; = p.P292L on NM_145028.5) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.328); catalogued as COSV99849588; called by muse, mutect2, varscan2
- ARSG | c.533G>A p.C178Y | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101477923; called by muse, mutect2, varscan2
- CHP1 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV100587168; called by muse, mutect2, varscan2
- KIF19 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as COSV63430431; called by muse, mutect2
- KYAT3 | c.454-1G>A p.X152_splice | Splice Site (SNP) | VAF 25/85 reads (29%) | catalogued as COSV53101013, COSV99556935; called by muse, mutect2, varscan2
- POLL | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100150445; called by muse, mutect2, varscan2
- PSMC4 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs576365261, COSV99338421; called by muse, mutect2, varscan2
- RASA1 | c.2546T>C p.L849S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs920219557, COSV99170575; called by muse, mutect2, varscan2
- TCN2 | c.429G>A p.G143= | Splice Region (SNP) | VAF 6/45 reads (13%) | catalogued as rs866432912, COSV53192838; called by muse, mutect2, varscan2
- TM7SF2 | c.496T>G p.S166A | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV99659825; called by muse, mutect2, varscan2
- TNS2 | c.4142G>A p.C1381Y (on ENST00000314250 / NM_170754.4; = p.C1391Y on NM_015319.2) | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036886; called by muse, mutect2, varscan2
- ZNF492 | c.986G>C p.R329T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.798); catalogued as COSV101513988, COSV101514057; called by mutect2, varscan2
- ZGRF1 | c.4022A>C p.N1341T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.296); called by muse, mutect2
- HBM | c.132G>A p.P44= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100720801; called by muse, mutect2
